Somatic mutation profile of tumor specimen MP2PRT-PATBIK-TMP1-A (aliquot MP2PRT-PATBIK-TMP1-A-1-0-D-A82L-36) from MP2PRT case MP2PRT-PATBIK, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.5 years (1,276 days).
Specimen MP2PRT-PATBIK-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fefbb6ae-9e1d-441a-a888-4d8b26f8b4ec.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATBIK-NM1-A (Blood Derived Cancer - Bone Marrow, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATBIK-NM1-A-1-0-D-A82L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5950d944-bd56-4e59-b010-3a5d0f2b40f3

The open-access MAF lists 17 somatic variants for this specimen: 14 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Silent 2, Nonsense Mutation 2, Intron 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DGKB | c.2054G>A p.R685Q | Missense Mutation (SNP) | VAF 28/472 reads (6%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.688); catalogued as rs61753126, COSV51769726; called by muse, mutect2
- DLGAP4 | c.1520G>A p.R507H | Missense Mutation (SNP) | VAF 68/544 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs757026394; called by muse, mutect2, varscan2
- DRD5 | c.253G>A p.V85M | Missense Mutation (SNP) | VAF 162/474 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.334); catalogued as rs1403024760, COSV58576627; called by muse, varscan2
- GRIA2 | c.2125G>A p.E709K | Missense Mutation (SNP) | VAF 17/385 reads (4%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV52402787; called by muse, mutect2
- KLRK1 | c.101G>A p.W34* | Nonsense Mutation (SNP) | VAF 59/209 reads (28%) | catalogued as rs550164323; called by muse, mutect2, varscan2
- LRRFIP1 | c.1753G>A p.V585I (on ENST00000392000 / NM_001137552.2; = p.V561I on NM_004735.4) | Missense Mutation (SNP) | VAF 46/178 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as rs780223024, COSV55250453; called by muse, mutect2, varscan2
- PAX5 | c.547G>A p.G183S | Missense Mutation (SNP) | VAF 146/600 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as rs398123063, CM139173, COSV63911050, COSV63911644; ClinVar: risk factor; called by muse, mutect2, varscan2
- RIPK4 | c.2380C>T p.R794W (on ENST00000352483; = p.R746W on NM_020639.3) | Missense Mutation (SNP) | VAF 254/876 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.868); catalogued as rs761871932; called by muse, mutect2, varscan2
- SLCO1C1 | c.530-1G>T p.X177_splice | Splice Site (SNP) | VAF 78/281 reads (28%) | catalogued as COSV99858865; called by muse, mutect2, varscan2
- TSBP1 | c.85C>T p.R29* | Nonsense Mutation (SNP) | VAF 115/344 reads (33%) | catalogued as rs149451141; called by muse, mutect2, varscan2
- PAX5 | c.98T>C p.L33P | Missense Mutation (SNP) | VAF 323/616 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PCK1 | c.1384T>C p.S462P | Missense Mutation (SNP) | VAF 116/302 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- SYNJ2 | c.4466T>C p.V1489A | Missense Mutation (SNP) | VAF 46/171 reads (27%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TRMT2A | c.1316T>C p.V439A | Missense Mutation (SNP) | VAF 124/368 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); called by muse, mutect2, varscan2
- CCR3 | c.666C>A p.I222= | Silent (SNP) | VAF 44/488 reads (9%) | called by muse, mutect2
- SIDT1 | c.1614T>C p.I538= | Silent (SNP) | VAF 87/261 reads (33%) | called by muse, mutect2, varscan2
- OPRM1 | c.1165-10894G>A | Intron (SNP) | VAF 29/274 reads (11%) | catalogued as rs547145262, COSV57823877; called by muse, mutect2, varscan2
